FM case AD11776 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/4ad5a683-d152-41ad-ba19-da02df0ddd40

Male, 47.4 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
